Somatic mutation profile of tumor specimen 0DNWKV from CCDI case PBCBYV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain stem; Age at diagnosis: 4.8 years (1,763 days).
Specimen 0DNWKV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78760a5e-20d8-475e-87f1-4f92a7102951.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNWJJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6dfe97ad-a750-4036-a403-0aaf96e28949

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CPT1C | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 66/453 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.023); catalogued as rs765721653; called by muse, mutect2, varscan2
- GUF1 | c.1753C>T p.R585W | Missense Mutation (SNP) | VAF 106/691 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs759581426, COSV55783765; called by muse, mutect2, varscan2
- UNC5D | c.2399C>T p.T800I | Missense Mutation (SNP) | VAF 26/762 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as COSV99773990; called by muse, mutect2
